Surgical pathology report (de-identified scan), TCGA case TCGA-61-1743, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1743-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: ADNEXA, RIGHT -

- A. MODERATELY DIFFERENTIATED MICROPAPILLARY SEROUS ADENOCARCINOMA OF THE OVARY (SEE COMMENT).
- B. UNREMARKABLE FALLOPIAN TUBE (SEE COMMENT).

PART 2: ADNEXA, LEFT -

- A. MODERATELY DIFFERENTIATED MICROPAPILLARY SEROUS ADENOCARCINOMA OF THE OVARY (SEE COMMENT).
- B. UNREMARKABLE FALLOPIAN TUBE (SEE COMMENT).

PART 3: UTERUS WITHOUT ADNEXA, 130-GRAMS -

- A. CHRONIC CYSTIC CERVICITIS.
- B. PROLIFERATIVE ENDOMETRIUM.
- C. LEIOMYOMA UTERI.

PART 4: CUL-DE-SAC, POSTERIOR, #1 -

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 5: CUL-DE-SAC, POSTERIOR, #2 -

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 6: BLADDER PERITONIUM, BIOPSY

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR (SEE COMMENT)

PART 7: PELVIC, RIGHT, BIOPSY -

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 8: PELVIC, LEFT, SIDEWALL -

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 9: LYMPH NODES, RIGHT, PELVIC -

THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 10: LYMPH NODES, OBTURATOR, RIGHT -

THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 11: LYMPH NODES, PELVIC, LEFT -

FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).

PART 12: LYMPH NODES, LEFT, OBTURATOR -

THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 13: LYMPH NODES, PERIAORTIC, LEFT -

LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 14: LYMPH NODES, PERIAORTIC, RIGHT -

TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 15: RIGHT GUTTER -

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR (SEE COMMENT).

PART 16: GUTTER, LEFT -

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 17: DIAPHRAGM, BIOPSY -

CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 18: VERMIFORM APPENDIX -

MUCOCELE WITH MUCINOUS CYSTADENOMA (SEE COMMENT).

PART 19: OMENTUM -

MATURE ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file c6cb6e40-e7a1-477d-be64-f954d706be30 (TCGA-61-1743.190B258B-D756-4872-B5F4-53C2D10E86B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).